Surgical pathology report (de-identified scan), TCGA case TCGA-76-6192, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Thomas Jefferson University, specimen TCGA-76-6192-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

Patient: [REDACTED]

[REDACTED] TCGA-76-6192

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

1. Left frontal lobe brain tumor (excision): glioblastoma, grade IV of IV (WHO scale), see microscopic description, see note
2. blood for research: specimen for research
3. left frontal lobe tumor for research: specimen for research
4. Left frontal lobe brain tumor (excision): glioblastoma, grade IV of IV (WHO scale), see microscopic description, see note
5. Left frontal lobe brain tumor (excision): glioblastoma, grade IV of IV (WHO scale), see microscopic description, see note.

Comment:

[REDACTED] reviewed selected slides and concurs with the presence of malignancy in this material.

[REDACTED]

Report Electronically Signed on [REDACTED]

This diagnostic report has been personally interpreted by the signatory of record.

Microscopic Description:

The tumor consists of a moderately to markedly pleomorphic proliferation of astrocytes with scattered multinucleated tumor giant cells. There is extensive non-pseudopalisading necrosis. There are many mitoses and extensive microvascular proliferation. In many areas, the microvascular proliferation becomes confluent. A reticulin stain demonstrates increased pericellular reticulin in areas near the confluent endothelial proliferation but there is no obvious entrapped

[page 2 of 4]
██████████

malignant cells. A GFAP stain is positive in tumor cells. There is, no clear evidence of a sarcomatous component based upon these stains.

Frozen Section Diagnosis:

- ██████████
1. Left frontal lobe tumor: Glioblastoma

Clinical History and Diagnosis:
Glioblastoma

Source of Specimen:

- 1: Left frontal lobe tumor
- 2: blood for research
- 3: left frontal lobe tumor for research
- 4: Left frontal lobe
- 5: Left frontal lobe

Gross Description:

████████████████████

1. Left frontal lobe tumor: Received fresh for frozen section in the specimen container labeled with patient name and "#1 left frontal lobe tumor" is a 2 x 2 by 0.5 cm aggregate of tan-white soft tissue. Touch prep is done. 40% of the specimen is submitted for frozen section. The specimen is submitted as follows:

A frozen section control

B-C. remainder of the specimen

2. blood for research:

3. left frontal lobe tumor for research:

4. Left frontal lobe: Received in formalin in the specimen container labeled with patient's name and "#4 left frontal lobe" is a 2.3 x 1.2 x 0.4 cm fragment of tan-white soft tissue. The specimen is entirely submitted in one cassette.

[page 3 of 4]
5. Left frontal lobe: Received in formalin in the specimen container labeled with patient's name and "#5 left frontal lobe" is a 2 x 2 0.5 x 0.8 cm aggregate of tan-red soft tissue. The specimen is entirely submitted in 3 cassettes.

Histology Laboratory

H&E

Part 1: Left frontal lobe tumor

GLIAL FIBRILLARY ACIDIC PROTEIN (GFAP)

SNOOKS RETICULIN

Immunohistochemistry Notes

1. Quantification of immunohistochemistry assay for ER and PR studies is by the method of Battiafora et.al. Applied Immunohistochemistry,

2. Hercept Test (DakoCytomation) Formalin fixed, paraffin embedded. Interpretation follows the manufacturer's recommendation.

Documented by

EGFR pharmDx Clone 2-18C9 Formalin fixed, paraffin embedded. Interpretation follows the manufacturer's recommendation.

Documented by

3. Analyte Specific Reagent (ASCR) Disclaimer. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR).

These tests were developed and their performance characteristics determined by the Hospital.

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not

[page 4 of 4]
necessary.

Source: NCI Genomic Data Commons file d012c763-2a80-4029-bc6e-a36f60f043e7 (TCGA-76-6192.D2A94594-7F5A-40F2-87FA-BEEE3FA5BE5B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).